Somatic mutation profile of cancer-model specimen HCM-BROD-0458-C15-85N (3D Organoid, passage 6; aliquot HCM-BROD-0458-C15-85N-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0458-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 57.6 years (21,052 days).
Specimen HCM-BROD-0458-C15-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06dc3205-7b79-48ac-88c6-6a11d2cfe477.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0458-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0458-C15-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff6a1a3d-e54d-40d8-b637-b63a10d1aeab

The open-access MAF lists 178 somatic variants for this specimen: 127 protein-altering or splice-affecting, 44 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 44, 3'UTR 3, 5'Flank 2, Frame Shift Del 2, Splice Region 1, Intron 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.831T>A p.C277* | Nonsense Mutation (SNP) | VAF 420/420 reads (100%) | hotspot (GDC flag); catalogued as rs1057523347, CM065496, COSV52676368, COSV52783531, COSV53164903; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARD | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 105/341 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV65600362; called by muse, mutect2, varscan2
- ABCA13 | c.13972T>G p.F4658V | Missense Mutation (SNP) | VAF 158/591 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV68944732, COSV68947840; called by muse, mutect2, varscan2
- ACSL6 | c.212G>A p.R71Q (on ENST00000379240; = p.R96Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372021457; called by muse, mutect2, varscan2
- ADAMTS20 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs577775989; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4374C>A p.N1458K | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.946); catalogued as COSV65878203; called by muse, mutect2, varscan2
- ADRA1A | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 173/382 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781501725; called by muse, mutect2, varscan2
- AGL | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752995564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 173/173 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs755697363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAT1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 112/2976 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769768383, COSV99678499; called by muse, mutect2
- CACNA1B | c.6802G>A p.A2268T | Missense Mutation (SNP) | VAF 254/2627 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1212751669; called by muse, mutect2, varscan2
- CASZ1 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1175922386, COSV59731144; called by muse, mutect2, varscan2
- CD320 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 113/342 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs944102596, COSV100035903; called by muse, mutect2, varscan2
- CHRNA5 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 144/331 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1280180578; called by muse, mutect2, varscan2
- COL14A1 | c.3923T>C p.I1308T | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1221646414; called by muse, mutect2, varscan2
- CRAMP1 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 209/412 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs1203663202; called by muse, mutect2, varscan2
- DCC | c.2382C>G p.I794M | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59136273; called by muse, mutect2, varscan2
- ECH1 | c.784G>C p.A262P | Missense Mutation (SNP) | VAF 32/726 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as rs1197445661; called by muse, mutect2
- EPS8L1 | c.530T>C p.L177S (on ENST00000201647 / NM_133180.3; = p.L50S on NM_017729.3) | Missense Mutation (SNP) | VAF 292/1138 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1019152509; called by muse, mutect2, varscan2
- ERICH6 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 104/432 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99901536; called by muse, mutect2, varscan2
- GABRB3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 166/329 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs756312674, COSV59476146; called by muse, mutect2, varscan2
- GEMIN4 | c.742_745del p.T248Cfs*4 | Frame Shift Del (DEL) | VAF 221/490 reads (45%) | catalogued as rs1430226794; called by mutect2, pindel, varscan2
- GINS3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 107/203 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753965914; called by muse, mutect2, varscan2
- GRID2 | c.561A>C p.K187N | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as COSV99942416; called by muse, mutect2, varscan2
- HECW1 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 178/606 reads (29%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); catalogued as rs1323812313, COSV67820911; called by muse, varscan2
- HOXC4 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 340/724 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as rs755761223, COSV57697583; called by muse, mutect2, varscan2
- IFT122 | c.2603A>T p.Y868F (on ENST00000348417 / NM_052989.3; = p.Y809F on NM_018262.4) | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs770762310; called by muse, mutect2, varscan2
- KLHL30 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 290/582 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs556457723; called by muse, mutect2, varscan2
- KRT12 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 250/691 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866761788, COSV52432390; called by muse, varscan2
- KRT23 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 232/994 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.258); catalogued as COSV52928558; called by muse, mutect2, varscan2
- LAMA1 | c.2183A>G p.Y728C | Missense Mutation (SNP) | VAF 244/499 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745529420, COSV101055620; called by muse, mutect2, varscan2
- LEO1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 150/300 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748039647, COSV55174713; called by muse, mutect2, varscan2
- MCF2 | c.1407A>C p.E469D | Missense Mutation (SNP) | VAF 108/245 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV100644503, COSV58489203; called by muse, mutect2, varscan2
- MED12L | c.5487C>A p.N1829K | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV56393371; called by mutect2, varscan2
- MEGF9 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 164/654 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV64236737; called by muse, mutect2, varscan2
- OR10X1 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 86/420 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1369179505, COSV100936635; called by muse, mutect2, varscan2
- OR2AP1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 144/362 reads (40%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.188); catalogued as rs771742216; called by muse, mutect2, varscan2
- OR5H1 | c.94T>A p.L32M | Missense Mutation (SNP) | VAF 176/508 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100641609, COSV63402638; called by muse, mutect2, varscan2
- OR5H15 | c.181T>G p.L61V | Missense Mutation (SNP) | VAF 172/472 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV62947385; called by muse, mutect2, varscan2
- PARP10 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 288/490 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782238694; called by muse, mutect2, varscan2
- PARP14 | c.3771G>A p.G1257= | Splice Region (SNP) | VAF 94/278 reads (34%) | catalogued as rs1465643634; called by muse, mutect2, varscan2
- PCNT | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 185/408 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs751935483, COSV64024888; called by muse, mutect2, varscan2
- PTPRS | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 160/538 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.079); catalogued as rs377318412, COSV53610187; called by muse, mutect2, varscan2
- PTPRT | c.1990T>G p.F664V | Missense Mutation (SNP) | VAF 52/1650 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV61965660, COSV62035244; called by muse, mutect2
- R3HDM2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs370585554; called by muse, mutect2, varscan2
- SERINC1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 143/291 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs145924073; called by muse, mutect2, varscan2
- SH3PXD2A | c.2992C>T p.R998W (on ENST00000369774 / NM_001365079.1; = p.R970W on NM_014631.2) | Missense Mutation (SNP) | VAF 220/451 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs561745856; called by muse, mutect2, varscan2
- SLC16A12 | c.1088G>T p.C363F | Missense Mutation (SNP) | VAF 172/324 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs749932458; called by muse, mutect2, varscan2
- SLC25A45 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 237/492 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.187); catalogued as rs770092256, COSV99587201; called by muse, mutect2, varscan2
- SVIL | c.5197G>A p.G1733S (on ENST00000355867 / NM_021738.3; = p.G1307S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/620 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs749301357, COSV63445525; called by muse, mutect2, varscan2
- SYNE3 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 222/458 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs774782727, COSV100515888; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4688C>T p.T1563I | Missense Mutation (SNP) | VAF 144/283 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs765583223; called by muse, mutect2, varscan2
- TOP2B | c.2462C>T p.A821V (on ENST00000264331 / NM_001330700.2; = p.A816V on NM_001068.3) | Missense Mutation (SNP) | VAF 120/424 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV51977095; called by muse, mutect2, varscan2
- TTN | c.74009C>G p.P24670R (on ENST00000591111; = p.P17246R on NM_003319.4) | Missense Mutation (SNP) | VAF 75/361 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV60164243; called by muse, mutect2, varscan2
- UGT1A6 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 248/501 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333719360, COSV59391983; called by muse, mutect2, varscan2
- UNC13C | c.3602T>G p.V1201G | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1471961392; called by muse, mutect2, varscan2
- USP13 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs144016604, COSV55867810; called by muse, mutect2, varscan2
- USP6NL | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 146/419 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs1400243199, COSV99509284; called by muse, mutect2, varscan2
- ZNF713 | c.440A>G p.H147R (on ENST00000633730 / NM_001366796.2; = p.H160R on NM_182633.3) | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1255734326, COSV101448710; called by muse, mutect2, varscan2
- AC011005.1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 200/636 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD30A | c.3508G>A p.V1170I (on ENST00000611781; = p.V1114I on NM_052997.2) | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BAG6 | c.1910C>A p.P637H (on ENST00000676571; = p.P590H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 343/727 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP3 | c.1611G>T p.L537F | Missense Mutation (SNP) | VAF 147/567 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BSN | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 349/729 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CACNA1H | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 452/837 reads (54%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNB1 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 134/945 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC141 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 147/296 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC148 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 155/298 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCSER2 | c.2406A>C p.R802S | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHST9 | c.1181A>C p.N394T | Missense Mutation (SNP) | VAF 123/395 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CLEC14A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 315/652 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNIH1 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 130/283 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- COPB2 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSDE1 | c.1089C>G p.I363M (on ENST00000358528 / NM_001007553.3; = p.I332M on NM_007158.6) | Missense Mutation (SNP) | VAF 180/542 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSMD2 | c.2596C>A p.H866N | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CTDP1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 488/489 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DHPS | c.822G>C p.K274N | Missense Mutation (SNP) | VAF 118/417 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DST | c.19462G>A p.A6488T (on ENST00000361203 / NM_001374722.1; = p.A4185T on NM_015548.5) | Missense Mutation (SNP) | VAF 251/390 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDRF1 | c.3586C>T p.H1196Y (on ENST00000356792 / NM_001202438.2; = p.H1162Y on NM_015608.2) | Missense Mutation (SNP) | VAF 127/289 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPC2 | c.2373A>C p.R791S | Missense Mutation (SNP) | VAF 213/215 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EPHX1 | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT3 | c.8105A>G p.E2702G | Missense Mutation (SNP) | VAF 168/390 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBLN2 | c.3272T>A p.L1091H | Missense Mutation (SNP) | VAF 452/688 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FHOD3 | c.737A>T p.N246I | Missense Mutation (SNP) | VAF 193/298 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FPR1 | c.64T>C p.Y22H | Missense Mutation (SNP) | VAF 157/526 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FSIP2 | c.17298T>G p.S5766R | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GOLGA8S | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2
- HECW1 | c.3659C>A p.P1220H | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HNRNPA1L2 | c.892A>C p.K298Q | Missense Mutation (SNP) | VAF 172/586 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IFNG | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGF2R | c.5374C>A p.P1792T | Missense Mutation (SNP) | VAF 181/370 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IGHG3 | c.594C>A p.H198Q | Missense Mutation (SNP) | VAF 243/515 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-21 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 157/572 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); called by muse, varscan2
- KIAA0895 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 142/454 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KSR1 | c.892C>A p.Q298K (on ENST00000644974 / NM_001367810.1; = p.Q161K on NM_014238.2) | Missense Mutation (SNP) | VAF 226/667 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- LDOC1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 254/544 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MAGEL2 | c.1717C>G p.P573A | Missense Mutation (SNP) | VAF 244/555 reads (44%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MAST1 | c.3982G>A p.V1328I | Missense Mutation (SNP) | VAF 261/729 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MECP2 | c.1129_1133del p.K377Pfs*14 | Frame Shift Del (DEL) | VAF 93/252 reads (37%) | called by mutect2, pindel, varscan2
- METTL8 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 149/306 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- NPAP1 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 151/311 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- NUDT9 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 130/272 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- OLFM1 | c.493A>G p.I165V (on ENST00000371793 / NM_001282611.2; = p.I147V on NM_014279.5) | Missense Mutation (SNP) | VAF 167/519 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- OR10T2 | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDK2 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 385/385 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PEX5L | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLK3 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 355/689 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PPP1R35 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 179/556 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PRDM15 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 178/179 reads (99%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRKAA2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 166/413 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, varscan2
- PRRC2C | c.7975G>A p.E2659K (on ENST00000367742; = p.E2657K on NM_015172.4) | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- QSER1 | c.3455C>G p.S1152C (on ENST00000399302; = p.S1281C on NM_001076786.3) | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIT2 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RYR2 | c.11656A>G p.S3886G | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STAB1 | c.5423C>T p.S1808F | Missense Mutation (SNP) | VAF 212/428 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- STARD9 | c.1072G>T p.V358F | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- STARD9 | c.1073T>A p.V358D | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TBK1 | c.1087C>G p.P363A | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THEGL | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 326/622 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.434); called by muse, varscan2
- TMC2 | c.825A>G p.I275M | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TMEM259 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 279/544 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TMEM26 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 116/564 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM9 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 140/668 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRIM37 | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 554/844 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF33A | c.625G>A p.E209K (on ENST00000458705 / NM_006974.3; = p.E210K on NM_006954.2) | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF33A | c.626A>T p.E209V (on ENST00000458705 / NM_006974.3; = p.E210V on NM_006954.2) | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF43 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ACTN2 | c.1338G>A p.A446= | Silent (SNP) | VAF 240/842 reads (29%) | catalogued as rs397516566, COSV63971577, COSV63972576; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMY2A | c.1170C>T p.D390= | Silent (SNP) | VAF 163/1164 reads (14%) | catalogued as rs545141011; called by muse, mutect2, varscan2
- BAIAP3 | c.2952G>A p.L984= | Silent (SNP) | VAF 150/299 reads (50%) | called by muse, mutect2, varscan2
- CACNA1B | c.1704G>A p.P568= | Silent (SNP) | VAF 208/2136 reads (10%) | catalogued as rs199970716, COSV53116222; called by muse, mutect2
- CACNA1I | c.5415C>T p.S1805= | Silent (SNP) | VAF 131/272 reads (48%) | catalogued as COSV100359224; called by muse, mutect2, varscan2
- CHMP5 | c.489A>G p.L163= | Silent (SNP) | VAF 144/2140 reads (7%) | called by muse, mutect2
- CILP | c.501G>A p.Q167= | Silent (SNP) | VAF 192/426 reads (45%) | called by muse, mutect2, varscan2
- COQ8A | c.96C>T p.I32= | Silent (SNP) | VAF 211/657 reads (32%) | catalogued as rs199919057; called by muse, mutect2, varscan2
- CYP4F2 | c.456G>A p.T152= | Silent (SNP) | VAF 175/799 reads (22%) | catalogued as rs370785925, COSV50002866; called by muse, mutect2, varscan2
- DNAH2 | c.10809G>A p.A3603= | Silent (SNP) | VAF 116/243 reads (48%) | catalogued as rs113847055; called by muse, mutect2, varscan2
- EFCAB3 | c.1023A>G p.G341= | Silent (SNP) | VAF 119/250 reads (48%) | called by muse, mutect2, varscan2
- FAT4 | c.174C>T p.G58= | Silent (SNP) | VAF 230/481 reads (48%) | called by muse, varscan2
- FRYL | c.3057A>C p.V1019= | Silent (SNP) | VAF 153/568 reads (27%) | called by muse, mutect2, varscan2
- GPR139 | c.57C>T p.P19= | Silent (SNP) | VAF 218/407 reads (54%) | catalogued as rs1183362113, COSV58504119; called by muse, mutect2, varscan2
- GPR37 | c.108C>T p.N36= | Silent (SNP) | VAF 202/694 reads (29%) | catalogued as COSV58259517; called by muse, mutect2, varscan2
- GPR52 | c.384T>G p.S128= | Silent (SNP) | VAF 178/899 reads (20%) | called by muse, mutect2, varscan2
- HIVEP1 | c.6342C>T p.R2114= | Silent (SNP) | VAF 98/234 reads (42%) | catalogued as COSV65100281; called by muse, mutect2, varscan2
- KCNG4 | c.648C>T p.S216= | Silent (SNP) | VAF 260/527 reads (49%) | catalogued as rs760236076; called by muse, mutect2, varscan2
- KRTAP19-5 | c.45C>T p.Y15= | Silent (SNP) | VAF 133/284 reads (47%) | catalogued as rs759270701, COSV100478566; called by muse, mutect2, varscan2
- MAGEL2 | c.1098G>T p.P366= | Silent (SNP) | VAF 204/428 reads (48%) | called by muse, varscan2
- MAGI2 | c.228G>A p.G76= | Silent (SNP) | VAF 181/670 reads (27%) | catalogued as rs758794152; called by muse, mutect2, varscan2
- MUC2 | c.516C>T p.S172= | Silent (SNP) | VAF 25/501 reads (5%) | called by muse, mutect2
- MUC5B | c.12462C>G p.T4154= | Silent (SNP) | VAF 309/707 reads (44%) | catalogued as rs779469762; called by muse, mutect2, varscan2
- PAX4 | c.894C>T p.A298= | Silent (SNP) | VAF 129/381 reads (34%) | catalogued as rs150850990; called by muse, mutect2, varscan2
- PDPR | c.2019A>G p.G673= | Silent (SNP) | VAF 79/490 reads (16%) | called by muse, mutect2
- PLD2 | c.2697C>T p.V899= | Silent (SNP) | VAF 214/493 reads (43%) | catalogued as COSV54006520; called by muse, mutect2, varscan2
- PNPLA5 | c.123C>T p.G41= | Silent (SNP) | VAF 219/523 reads (42%) | catalogued as COSV99336777; called by muse, mutect2, varscan2
- PROX2 | c.1725G>A p.S575= (on ENST00000556489 / NM_001243007.1; = p.S348= on NM_001080408.2) | Silent (SNP) | VAF 149/278 reads (54%) | catalogued as rs764899107, COSV71519996; called by muse, mutect2, varscan2
- PRR32 | c.558C>T p.T186= | Silent (SNP) | VAF 18/368 reads (5%) | catalogued as rs1330938145; called by muse, mutect2
- PTGDR2 | c.1050G>A p.S350= | Silent (SNP) | VAF 312/644 reads (48%) | catalogued as rs1469219018; called by muse, varscan2
- RASGRP4 | c.1408C>T p.L470= | Silent (SNP) | VAF 332/531 reads (63%) | catalogued as rs781649734; called by muse, mutect2, varscan2
- SEMA3E | c.1161T>C p.N387= | Silent (SNP) | VAF 107/291 reads (37%) | called by muse, mutect2, varscan2
- SLC12A8 | c.423T>C p.F141= | Silent (SNP) | VAF 129/382 reads (34%) | called by muse, mutect2, varscan2
- SLC9A7 | c.1485G>T p.A495= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- STK32A | c.1107G>A p.R369= | Silent (SNP) | VAF 204/204 reads (100%) | called by muse, mutect2, varscan2
- TMEM128 | c.423G>C p.V141= (on ENST00000382753 / NM_001297552.2; = p.V117= on NM_032927.3) | Silent (SNP) | VAF 78/169 reads (46%) | catalogued as rs751985121; called by muse, mutect2, varscan2
- TRBV24-1 | c.231A>G p.G77= | Silent (SNP) | VAF 146/463 reads (32%) | called by muse, mutect2, varscan2
- TRPC4 | c.606C>A p.A202= | Silent (SNP) | VAF 403/411 reads (98%) | catalogued as rs758760853; called by muse, mutect2, varscan2
- TTC28 | c.429C>T p.A143= | Silent (SNP) | VAF 169/328 reads (52%) | catalogued as rs541533581; called by muse, mutect2, varscan2
- UNC79 | c.5787G>A p.L1929= (on ENST00000393151 / NM_001346218.2; = p.L1752= on NM_020818.5) | Silent (SNP) | VAF 174/364 reads (48%) | called by muse, mutect2, varscan2
- XRRA1 | c.1053C>T p.F351= | Silent (SNP) | VAF 84/376 reads (22%) | catalogued as rs748371055, COSV58499968; called by muse, mutect2, varscan2
- ZC3H11B | c.2235C>A p.G745= | Silent (SNP) | VAF 116/924 reads (13%) | called by muse, varscan2
- ZNF587 | c.1407T>C p.C469= | Silent (SNP) | VAF 167/788 reads (21%) | called by muse, varscan2
- ZSCAN18 | c.1488C>T p.S496= | Silent (SNP) | VAF 403/864 reads (47%) | catalogued as rs1304419328, COSV53735055; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148242 C>T | 5'Flank (SNP) | VAF 185/380 reads (49%) | catalogued as rs370075756; called by muse, mutect2
- C2orf16 | chr2:27576146 G>A | 5'Flank (SNP) | VAF 167/366 reads (46%) | catalogued as rs538908364, COSV101284453; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+22294T>C | Intron (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- MFSD4B | c.*270C>G | 3'UTR (SNP) | VAF 331/331 reads (100%) | called by muse, mutect2, varscan2
- PCIF1 | c.-162C>T | 5'UTR (SNP) | VAF 148/451 reads (33%) | called by muse, mutect2, varscan2
- WDR64 | c.*298C>A | 3'UTR (SNP) | VAF 52/494 reads (11%) | called by muse, varscan2
- WDR64 | c.*299A>T | 3'UTR (SNP) | VAF 56/522 reads (11%) | called by muse, mutect2, varscan2
